Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A76O, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A76O-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Astrocytoma, grade II 9400/3
Site ^{C61K} Brain, supratentorial NOS
C71.0
Path
Brain, parietal lobe
C71.3
9/30/13

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: Location: Received:
Gender: M Acct: Reported:
Physician(s):
Phy Location:

Clinical History

-old man has past history of left leg amputation for cartilaginous tumor (Ollier's disease), and has several intra axial, intracranial tumors consistent with low histological grade gliomas. Patient experiences medically intractable complex partial epilepsy.

Operative Diagnoses

Medically intractable complex partial epilepsy

Operation / Specimen

A: Para sagittal, biopsy
B: Inferior parietal, biopsy

Pathologic Diagnosis

A. Brain, parasagittal, excision:

1. Low histological grade glioma, consistent with diffuse astrocytoma (WHO grade 2).
2. IDH1-R132H mutation: Positive.
3. MIB-1 proliferation index: > 9%.
4. 1p, 19q LOH: Negative.
5. MGMT: Low positive.

B. Brain, inferior parietal, excision:

1. Neoplastic glial infiltrate, sparse.
2. Architectural features: Uncertain.

See Microscopy Description and Comment.

Comment

Part A.

This specimen is portions of cerebrum that are moderately infiltrated by a glial neoplastic proliferation that has a mixed oligo astrocytic phenotype, with uniform round/ovoid nuclei frequently surrounded by halos. However, the neoplastic cells are devoid of the 1p, 19q deletion characteristic of oligodendrogliomas. Mitotic figures are found with great difficulty, and there is not microvascular proliferation or tumor necrosis. The MIB-1 proliferation index is greater than 9% (as normal native cells are entered in the total nuclear count; the index is probably no more than 15%).

The findings are interpreted as those of a low histological grade glial neoplasm that has molecular features of astrocytoma. The elevated cycling activity may portend a heightened aggressive potential.

Part B.

Surgical Pathology

Page 2 of 4

This specimen is three small fragments of cerebral cortex in which, because of the small size and orientation of the fragments, it is difficult to evaluate the cortical architectural features. Furthermore, the IDH1 stain demonstrates a

[page 2 of 4]
somewhat sparse sprinkling of the cortex by neoplastic glial cells, which interferes even more with evaluation of the distribution of normal cells. There is not obvious architectural distortion, dysmorphic neuronal element, or balloon cells.

The findings are interpreted as a glial neoplasm sparsely infiltrating the cerebral cortex; and non conclusive of cortical dysplasia

The features in both specimens may be correlated with clinical, imaging, electrophysiological, and operative findings

for their interpretation and patient's follow up.

Electronically Signed Out

Consultant: Senior Staff Pathologist
Senior Staff Pathologist

Procedures/Addenda

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: **Date Reported:**

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S1592, D1S552, D19S412, D19S606, D19S1182 and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A1). DNA extracted from a corresponding blood specimen was used as a normal reference control.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Surgical Pathology

Page 3 of 4

Electronically Signed Out

, Senior Staff Pathologist

[page 3 of 4]
MGMT Promoter Methylation

Date Ordered: **Date Reported:**

Interpretation

LOW POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A1)

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Electronically Signed Out

, Senior Staff Pathologist

Gross Description

A.

Para sagittal, biopsy: CONTAINER LABEL: para sagittal.

FIXATIVE: Formalin. NO. PIECES: 5. SIZE/VOL: 2-4 mm. tan brain tissue CASSETTES: 1

B.

Inferior parietal, biopsy: CONTAINER LABEL: inferior parietal.

FIXATIVE: Formalin. NO. PIECES: 2. SIZE/VOL: 3-4 mm. CASSETTES: 1

Microscopic Description

IMMUNOHISTOCHEMISTRY:

Part A: The GFAP demonstrates a rather delicate gliofibrillary background. The tumor cells are heavily and

uniformly reactive with IDH1. With the MIB-1 there is a proliferation index of more than 9%, since the normal native

nuclei are included in the total cell count.

Surgical Pathology

Page 4 of 4

Part B: The IDH1 evinces a sparse sprinkling of positive glial neoplastic nuclei sprinkled throughout the cerebral

cortex. The GFAP demonstrates absence of reactive astrocytes. The CD163 depicts slight dendritic microglial

unrest, probably associated with previous mechanical manipulation. The NeuN and NFP highlight a thin, tangentially sectioned cerebral cortex that overall has reasonable well preserved layering, without overt disorganization or dysmorphism.

ICD-9(s): 191.0 191.0

[page 4 of 4]
Billing Fee Code(s): A:

B:

LOH 1p19q:

MGMT:

Histo Data

Part A: Para sagittal, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

mGFAP-DA x 1 1

H&E x 1 1

IDH1-sld x 1 1

LOH-curly x 1 1

MGMT-curly x 1 1

MIB1-DA x 1 1

Part B: Inferior parietal, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

CD163 Vector x 1 1

mGFAP-DA x 1 1

H&E x 1 1

IDH1-sld x 1 1

NeuN x 1 1

NF2F11 x 1 1

Rct 3 H&E x 1 1

Source: NCI Genomic Data Commons file d681ea31-b579-498c-93f9-905589f05749 (TCGA-DU-A76O.64ED6980-61B9-4F1C-B7EE-B3459BD7E398.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).